Gene-level copy-number profile of tumor specimen C3N-01756-01 from CPTAC case C3N-01756, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.7 years (22,915 days).
Specimen C3N-01756-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ffbc0f2-0787-4022-8b0c-fb1559894558.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01756-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/a6585e2b-6b58-4b40-893f-d6881a2e1bc8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 152; copy number 1: 17,741; copy number 2: 30,984; copy number 3: 7,327; copy number 4: 1,366; copy number 5: 953; copy number 6: 51; copy number 7: 83; copy number 8: 53; copy number 10: 91; copy number 12: 8; copy number 13: 39; copy number 14: 17; copy number 18: 18; copy number 27: 3; copy number 32: 4; copy number 104: 14; copy number 117: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr3:11,272,309–11,557,665, 4 genes (within-gene range 0–1): ATG7, AC083855.1, AC026185.1, AC022001.1.
- chr9:20,341,669–22,455,740, 65 genes (broad region; genes not listed).
- chr9:42,566,679–42,569,353, 2 genes: BX088651.4, BX088651.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,335 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,175,748–149,556,361, 5 genes, copy number 5–6 (within-gene range 5–8): AC245297.3, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr2:242,175,181–242,175,634, 1 gene, copy number 6: RPL23AP88.
- chr5:56,099,680–56,233,330, 1 gene, copy number 5 (within-gene range 4–5): ANKRD55.
- chr5:56,192,530–58,863,414, 42 genes, copy number 5–13: C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1.
- chr7:54,419,444–55,878,164, 38 genes, copy number 5: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2.
- chr11:69,294,151–70,436,584, 35 genes, copy number 14–18: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:66,767–34,249,958, 831 genes, copy number 5 (broad region; genes not listed).
- chr17:30,378,927–34,174,964, 136 genes, copy number 7–117 (within-gene range 2–117) (broad region; genes not listed).
- chr17:34,155,566–34,165,736, 1 gene, copy number 7 (within-gene range 2–7): AC004147.2.
- chr17:39,603,536–41,812,604, 150 genes, copy number 10–104 (broad region; genes not listed).
- chr17:43,014,607–43,305,397, 26 genes, copy number 5: VAT1, RND2, BRCA1, RPL21P4, NBR2, AC135721.2, AC135721.1, AC060780.1, BRCA1P1, AC060780.2, NBR1, TMEM106A, CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2.
- chr17:43,360,041–43,361,361, 1 gene, copy number 5: AC109326.1.
- chr17:44,290,856–45,372,057, 60 genes, copy number 5–6: RN7SL507P, RUNDC3A-AS1, U3, RNU6-453P, RUNDC3A, SLC25A39, AC003043.1, GRN, FAM171A2, RPL7L1P5, ITGA2B, GPATCH8, RN7SL258P, AC103703.1, FZD2, AC091152.3, SMCO4P1, LINC01180, MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1, ADAM11, AC005180.2, AC005180.1, GJC1, HIGD1B, EFTUD2, RN7SL405P, CCDC103, FAM187A, GFAP, KIF18B, MIR6783, AC015936.1, NMT1, C1QL1, AC015936.2, DCAKD, Y_RNA, PLCD3, MIR6784, ACBD4, AC142472.1, HEXIM1, AC138150.1, HEXIM2, AC138150.2, AC008105.3, FMNL1, AC008105.1, AC008105.2, MAP3K14-AS1, SPATA32, MAP3K14, RNA5SP443, AC003070.2.
- chr21:19,130,523–19,760,128, 8 genes, copy number 12: AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1.

Autosomal genes at a single copy (total copy number 1): 14,960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
